Gene-level copy-number profile of specimen HCM-BROD-0762-C49-85B from HCMI case HCM-BROD-0762-C49, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Abdominal fibromatosis; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 15.9 years (5,799 days).
Specimen HCM-BROD-0762-C49-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 19.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c0bdaff4-62bc-41f6-bbb6-a3faeda80e9c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0762-C49-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,221 have no estimate.
https://portal.gdc.cancer.gov/files/bc145800-2dc1-4d60-be1f-c019b419c4a8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 51; copy number 2: 57,578; copy number 3: 773.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 51. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
